TARGET case TARGET-40-NAAFKF — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4c55494f-03d4-54f0-b993-83bbb4310f10

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 16 years; Vital status: Dead; Days to death: 261 days.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.0; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 16.8 years (6,129 days); Year of diagnosis: 2011; Metastasis at diagnosis: No Metastasis; Days to last follow up: 261 days.
   Pathology details: Necrosis percent: 50.
   Treatment given: Protocol identifier: IHRT.
   Treatment given: Therapeutic agents: Cisplatin.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Etoposide.
   Treatment given: Therapeutic agents: Ifosfamide.
   Treatment given: Therapeutic agents: Methotrexate.

Follow-up (2 entries)
- Days to follow up: 149 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 149 days; Days to first event: 149 days; First event: Relapse.
- Days to follow up: 261 days; Year of follow up: 2012.

Biospecimens (1 sample)
- Sample TARGET-40-NAAFKF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAFKF-01A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 99
- % Non Tumor Nuclei: Top from Biopsy: 1
- % Cellular Tumor: Top from Biopsy: 97
- % Normal: Top from Biopsy: 0
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 3
- % Tumor Nuclei: Bottom from Biopsy: 99
- % Non Tumor Nuclei: Bottom from Biopsy: 1
- % Cellular Tumor: Bottom from Biopsy: 99
- % Normal: Bottom from Biopsy: 0
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 1
- PASS/FAIL: pass

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 261
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Arm/hand
- Specific tumor site: Radius
- Specific tumor region: Distal
- Definitive Surgery: Amputation
- Primary site progression: No
- Site of initial relapse: Lung
- Histologic response: Stage 1/2 (0-90 % necrosis)
- Relapse Type: Systemic
- Therapy: MTX, Adria, Cis, Ifos, VP-16
